CCDI case PBCDRD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/543f5c79-37fe-459a-aa2e-e4da5f0eeaa8

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 2.4 years (891 days).

Biospecimens (3 samples)
- Sample 0DPHSZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPHT2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DPHTD: Tissue type: Tumor; Specimen type: Solid Tissue.
